Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4184, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4184-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Partial gastrectomy. Tumor Site: Body, greater curvature. Tumor configuration: Exophytic (polypoid). Tumor size: 8.0 x 7.0 x 2.5 cm. Histologic type: Adenocarcinoma. Histologic grade: Moderately differentiated. Extent of invasion: Serosa (visceral peritoneum). Lymph nodes: 1 of 8 lymph nodes positive for metastasis. Margins – Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

STOMACH TISSUE CHECKLIST. Specimen type: Partial gastrectomy. Tumor Site: Body, greater curvature. Tumor configuration: Exophytic (polypoid). Tumor size: 8.0 x 7.0 x 2.5 cm. Histologic type: Adenocarcinoma. Histologic grade: Moderately differentiated. Extent of invasion: Serosa (visceral peritoneum). Lymph nodes: 1 of 8 lymph nodes positive for metastasis. Margins – Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 09c169a6-8ea3-46de-b781-2f774aad7862 (TCGA-BR-4184.3893D873-2A7F-4BBD-943A-FEA998D34FD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).